Somatic mutation profile of tumor specimen TCGA-C5-A8YQ-01A (aliquot TCGA-C5-A8YQ-01A-11D-A37N-09) from TCGA case TCGA-C5-A8YQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 79.0 years (28,873 days).
Specimen TCGA-C5-A8YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 467a115d-1cd4-4931-b566-e55f386ca195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8YQ-10A (Blood Derived Normal), aliquot TCGA-C5-A8YQ-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aee7eab1-676e-4891-ba72-c1b5eb47d836

The open-access MAF lists 172 somatic variants for this specimen: 133 protein-altering or splice-affecting, 32 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 32, Nonsense Mutation 7, Intron 5, Frame Shift Del 3, Splice Site 3, In Frame Del 1, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 55/73 reads (75%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- AC126283.2 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV101144565; called by muse, mutect2, varscan2
- ACAN | c.7381G>A p.E2461K (on ENST00000560601 / NM_001369268.1; = p.E2385K on NM_001135.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs183636867; called by muse, mutect2, varscan2
- ACSF2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99366260; called by muse, mutect2, varscan2
- ACTB | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs1484491064, COSV59318696, COSV59320746; called by muse, mutect2, varscan2
- ACTRT1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV64419728; called by muse, mutect2, varscan2
- AMOTL2 | c.1756_1764del p.A586_A588del | In Frame Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs748357501; called by mutect2, pindel, varscan2
- AP001781.2 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.111); catalogued as rs199757538, COSV52791634, COSV99500085; called by muse, mutect2, varscan2
- ASB5 | c.703A>T p.T235S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV99641919; called by muse, mutect2, varscan2
- ATP10A | c.3961C>T p.P1321S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100791392, COSV63523387; called by muse, mutect2, varscan2
- ATXN7L2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100881354; called by muse, mutect2, varscan2
- BCAS1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs148582842; called by muse, mutect2, varscan2
- BMS1 | c.3531G>C p.K1177N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100996771; called by muse, mutect2, varscan2
- CADM4 | c.790T>A p.S264T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99731604; called by muse, mutect2, varscan2
- CALM3 | c.214A>T p.M72L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.015); catalogued as COSV99355274; called by muse, mutect2, varscan2
- CASC3 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.143); catalogued as rs139973585; called by muse, mutect2, varscan2
- CCDC124 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs760827266, COSV101506504; called by muse, mutect2, varscan2
- CCDC150 | c.3094C>T p.H1032Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99777165; called by muse, mutect2, varscan2
- CCDC172 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100319885; called by muse, mutect2
- CCN4 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs778202911, COSV51533217; called by muse, mutect2
- CDKN1B | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 72/99 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV99964006; called by muse, mutect2, varscan2
- CFAP47 | c.1613C>G p.S538W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.672); catalogued as COSV99935514; called by muse, mutect2, varscan2
- CHST1 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100346381; called by muse, mutect2, varscan2
- CSNK1G3 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV100631651; called by muse, mutect2, varscan2
- CSRNP3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100086077; called by muse, mutect2, varscan2
- CTCF | c.890A>T p.H297L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99865989; called by muse, mutect2, varscan2
- CTDSP1 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99812038; called by muse, mutect2, varscan2
- CYLC1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.153); catalogued as COSV100255042; called by muse, mutect2, varscan2
- DCAF8L1 | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV101491501, COSV71595191; called by muse, mutect2, varscan2
- ELOVL5 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100439785; called by muse, mutect2
- EP300 | c.5296C>T p.Q1766* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99609259; called by muse, mutect2
- ERBB4 | c.2253G>C p.K751N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53605796, COSV99628405; called by muse, mutect2, varscan2
- ERN2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99891919; called by muse, mutect2, varscan2
- F2RL1 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99688845; called by muse, mutect2, varscan2
- FBF1 | c.2302G>A p.E768K (on ENST00000586717; = p.E782K on NM_001319193.1) | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as COSV100045388; called by muse, mutect2, varscan2
- FCGRT | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV99571388; called by muse, mutect2, varscan2
- FRMPD1 | c.1218+2T>C p.X406_splice | Splice Site (SNP) | VAF 11/15 reads (73%) | catalogued as COSV100899596; called by muse, mutect2, varscan2
- GLOD5 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs782200472, COSV57489108; called by muse, mutect2, varscan2
- GLRA2 | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99490424, COSV99491393; called by muse, mutect2, varscan2
- GPR158 | c.900C>G p.F300L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV100894001; called by muse, mutect2, varscan2
- GPR158 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV100894003; called by muse, mutect2, varscan2
- GTDC1 | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.088); catalogued as COSV99599090, COSV99601194; called by muse, mutect2, varscan2
- GTSE1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs765217704, COSV101483231; called by muse, mutect2
- IFIT1B | c.1072A>C p.K358Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV100879091; called by muse, mutect2, varscan2
- IGDCC4 | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100733023; called by muse, mutect2, varscan2
- IGF2BP3 | c.161T>C p.I54T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1289316910, COSV99325622; called by mutect2, varscan2
- IGKJ4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | PolyPhen benign (0.216); catalogued as rs145002796; called by muse, mutect2, varscan2
- IL13RA2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs375241228, COSV54564294; called by muse, mutect2, varscan2
- IPCEF1 | c.1017G>C p.L339F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.115); catalogued as COSV99500065; called by muse, mutect2, varscan2
- IRF2BP2 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100784349; called by muse, mutect2, varscan2
- KAT6A | c.4768G>A p.G1590S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.705); catalogued as rs751096264, COSV99705529; ClinVar: likely benign; called by muse, varscan2
- KIAA0100 | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV101197358, COSV66495243; called by muse, mutect2, varscan2
- KIF4A | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV65545377; called by muse, varscan2
- KLHL11 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV59861539, COSV59861587; called by muse, mutect2, varscan2
- LRP1B | c.1915C>G p.L639V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101258243; called by muse, mutect2, varscan2
- LRRCC1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369833810; called by muse, mutect2, varscan2
- LRRN3 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.589); catalogued as COSV100072009; called by muse, mutect2, varscan2
- MAGEA1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100756664; called by muse, mutect2, varscan2
- MAGEH1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as rs147576211, COSV61678694; called by muse, mutect2, varscan2
- MAP4K1 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs138670494, COSV101204307; called by muse, mutect2, varscan2
- MIXL1 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100830822; called by muse, mutect2, varscan2
- MYBPHL | c.1051A>C p.K351Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV100848890; called by muse, mutect2, varscan2
- NAA10 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100892453; called by muse, mutect2, varscan2
- NCKAP1L | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV53206034, COSV99515384; called by muse, mutect2, varscan2
- NLRP10 | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100149392, COSV100149826; called by muse, mutect2, varscan2
- NMRK1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as COSV100738044; called by muse, mutect2, varscan2
- NOTCH1 | c.4193A>G p.Y1398C | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99489921; called by muse, mutect2, varscan2
- OLAH | c.587C>G p.S196C (on ENST00000378228 / NM_001039702.3; = p.S249C on NM_018324.3) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100984801; called by muse, mutect2, varscan2
- OR1F1 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100484476; called by muse, mutect2, varscan2
- OR52A1 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100200534; called by muse, mutect2, varscan2
- OR6B3 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100097470; called by muse, mutect2, varscan2
- OXLD1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV100235744; called by muse, mutect2, varscan2
- P4HB | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV100515880, COSV58939761; called by muse, mutect2, varscan2
- PAXBP1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99269403; called by muse, mutect2, varscan2
- PCDH12 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as COSV51521144; called by muse, mutect2, varscan2
- PCDH19 | c.3221C>G p.S1074C (on ENST00000373034 / NM_001184880.2; = p.S1026C on NM_020766.3) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs1422167083, COSV99720339; called by muse, mutect2, varscan2
- PCDHA4 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV100793244; called by muse, mutect2, varscan2
- PCDHGA6 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99542426; called by muse, mutect2, varscan2
- PCDHGA8 | c.1341C>A p.D447E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs770076493, COSV99542427; called by muse, mutect2, varscan2
- PCDHGA9 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.033); catalogued as COSV99542429; called by muse, mutect2, varscan2
- PCLO | c.5650T>C p.Y1884H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV100434759; called by muse, mutect2, varscan2
- PDE7A | c.1074G>C p.L358F (on ENST00000401827 / NM_001242318.3; = p.L332F on NM_002603.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101052696; called by muse, mutect2, varscan2
- PIGG | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV99574119; called by muse, mutect2, varscan2
- PIK3R4 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100768525, COSV63239463; called by muse, mutect2, varscan2
- POU5F1 | c.381G>C p.E127D | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV99463140; called by muse, mutect2, varscan2
- PTER | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV100126760; called by muse, mutect2, varscan2
- PTPRF | c.4119G>T p.E1373D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV100741055; called by muse, varscan2
- PXDN | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99414254; called by muse, mutect2, varscan2
- RAI1 | c.4711G>A p.A1571T | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.726); catalogued as rs779651867, COSV99884585; ClinVar: uncertain significance; called by muse, mutect2
- RALGPS2 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV61339748; called by muse, mutect2, varscan2
- RANBP9 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99163592; called by muse, mutect2, varscan2
- REXO5 | c.1719+2T>A p.X573_splice | Splice Site (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99759323; called by muse, mutect2, varscan2
- RFX4 | c.921C>A p.N307K (on ENST00000392842 / NM_213594.3; = p.N213K on NM_032491.6) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.932); catalogued as COSV99986113; called by muse, mutect2, varscan2
- RGS7 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as rs1391178312, COSV100469287; called by muse, mutect2, varscan2
- RNFT2 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs138653629; called by muse, mutect2, varscan2
- SEL1L2 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1568991992; called by muse, mutect2
- SEPTIN7 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100621857; called by muse, mutect2, varscan2
- SETBP1 | c.2395T>A p.F799I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99954104; called by muse, mutect2, varscan2
- SH2B1 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100451156; called by muse, varscan2
- SH2B1 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.458); catalogued as COSV100451159; called by muse, varscan2
- SLC27A6 | c.1452C>T p.F484= | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99322375, COSV99323164; called by muse, mutect2, varscan2
- SLK | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211915; called by muse, mutect2
- SMPDL3A | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV100868718, COSV63755370; called by muse, mutect2, varscan2
- SNAP25 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.67); catalogued as COSV99655116; called by muse, mutect2, varscan2
- SPAG17 | c.5191G>T p.G1731* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100309786; called by muse, mutect2, varscan2
- SPON1 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs782564186, COSV100116335; called by muse, mutect2, varscan2
- SRPK1 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100644393, COSV60411154; called by muse, mutect2, varscan2
- STARD13 | c.3265C>G p.L1089V (on ENST00000336934 / NM_001243476.3; = p.L971V on NM_052851.3) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV99716158; called by muse, mutect2, varscan2
- TDP2 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV61967723; called by muse, mutect2, varscan2
- TELO2 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs747764029, COSV99248542; called by muse, varscan2
- TMEM131L | c.3209C>T p.S1070F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99547804; called by muse, mutect2, varscan2
- TP53 | c.69G>A p.W23* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as COSV52932376, COSV53724279; called by muse, mutect2, varscan2
- TPTE2 | c.577C>G p.Q193E (on ENST00000400230 / NM_199254.2; = p.Q116E on NM_130785.3) | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as COSV99690656; called by muse, mutect2, varscan2
- TRIML2 | c.1052C>A p.T351N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100456202, COSV58717537; called by muse, mutect2, varscan2
- TWNK | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs373068264; called by muse, mutect2, varscan2
- UBE3B | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99784239; called by muse, mutect2, varscan2
- UGT2B17 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100497260; called by muse, mutect2, varscan2
- VPS13B | c.2395C>T p.Q799* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100662706; called by muse, mutect2, varscan2
- WNK3 | c.2692C>G p.P898A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100671735; called by muse, mutect2, varscan2
- XDH | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV101052340; called by muse, mutect2, varscan2
- ZBTB16 | c.765C>A p.D255E | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100251791; called by muse, mutect2, varscan2
- ZNF30 | c.1061G>C p.R354T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs768939075, COSV100340675; called by muse, mutect2, varscan2
- ZNF33A | c.1899G>C p.E633D (on ENST00000458705 / NM_006974.3; = p.E634D on NM_006954.2) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs750562291, COSV100276038; called by muse, mutect2, varscan2
- ZNF518B | c.2965C>T p.H989Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV58723581; called by muse, mutect2, varscan2
- ZSWIM8 | c.2216G>A p.G739E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101290045; called by muse, mutect2, varscan2
- ADAMTS16 | c.1564T>G p.F522V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AJUBA | c.1063del p.L355Wfs*55 | Frame Shift Del (DEL) | VAF 16/23 reads (70%) | called by mutect2, pindel, varscan2
- DSG3 | c.1608_1611del p.A537Yfs*45 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by pindel, varscan2*
- ESRRB | c.281T>A p.M94K | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.191); called by muse, mutect2
- KIF26B | c.6199G>C p.E2067Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- NBN | c.960G>C p.K320N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PPP1CB | c.568del p.R190Dfs*41 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- TRIM46 | c.2041G>T p.A681S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.304); called by muse, mutect2
- ALKBH1 | c.1169G>A p.*390= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99380692; called by muse, mutect2, varscan2
- APOB | c.8034G>A p.Q2678= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV51935737; called by muse, mutect2, varscan2
- ASIC3 | c.1533C>T p.P511= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99877174; called by muse, mutect2, varscan2
- ATMIN | c.1485C>A p.T495= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100214702; called by muse, varscan2
- CCAR2 | c.2745G>A p.E915= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV99374192; called by muse, mutect2, varscan2
- DDIT4L | c.327C>T p.H109= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs368682316; called by muse, mutect2, varscan2
- DISP3 | c.987C>T p.S329= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- DLGAP2 | c.990G>A p.A330= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1284127378, COSV101421075; called by muse, mutect2, varscan2
- DNAH2 | c.1083C>T p.L361= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1387938289, COSV99318359; called by muse, varscan2
- DNAH3 | c.5661C>T p.F1887= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99769075; called by muse, mutect2, varscan2
- EWSR1 | c.651G>A p.P217= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as rs368583920, COSV58421334; called by muse, mutect2, varscan2
- FBLN2 | c.534C>T p.H178= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs374848366; called by muse, mutect2, varscan2
- FGFR4 | c.2310C>T p.D770= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs574277502, COSV99449709; called by muse, mutect2, varscan2
- FKBP10 | c.555G>A p.L185= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100387929; called by muse, mutect2
- FRY | c.3030A>G p.K1010= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV100969594; called by muse, mutect2, varscan2
- GALNT18 | c.417C>G p.L139= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99925216; called by muse, mutect2, varscan2
- IMPG2 | c.840A>G p.A280= | Silent (SNP) | VAF 95/115 reads (83%) | catalogued as COSV99516032; called by muse, mutect2, varscan2
- IRAK1 | c.1521G>A p.R507= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100889028; called by muse, mutect2
- LMBRD1 | c.682T>C p.L228= (on ENST00000649011; = p.L206= on NM_018368.4) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100992650; called by muse, mutect2, varscan2
- LRBA | c.6750C>A p.I2250= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100841932; called by muse, mutect2, varscan2
- NAV3 | c.2601G>A p.Q867= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV57098045, COSV57110468; called by muse, mutect2, varscan2
- NRCAM | c.1044C>T p.A348= (on ENST00000379028 / NM_001371124.1; = p.A342= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV100695077; called by muse, mutect2, varscan2
- PREB | c.846C>G p.L282= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99574664; called by muse, mutect2, varscan2
- RAD21 | c.198C>T p.I66= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV52064419, COSV99815436; called by muse, mutect2, varscan2
- SCN7A | c.3564G>A p.L1188= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV101313306; called by muse, mutect2, varscan2
- SGPL1 | c.1290C>G p.L430= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100940409; called by muse, mutect2, varscan2
- SI | c.3567A>G p.G1189= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100016405; called by muse, mutect2, varscan2
- SLC25A25 | c.1315C>T p.L439= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as COSV100895352; called by muse, mutect2, varscan2
- VPS54 | c.1365C>T p.F455= | Silent (SNP) | VAF 11/242 reads (5%) | catalogued as rs1242803040, COSV99708453; called by muse, mutect2
- XIRP2 | c.4719C>T p.T1573= (on ENST00000628543; = p.T1748= on NM_152381.6) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs541451171, COSV99745311; called by muse, varscan2
- ZBTB18 | c.201C>T p.S67= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs202227336, COSV62398251; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1224G>A p.E408= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99837683; called by muse, mutect2, varscan2
- BMP1 | c.2108-641C>G | Intron (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100109856; called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3951G>A | Intron (SNP) | VAF 16/67 reads (24%) | catalogued as COSV100505636, COSV100506146; called by muse, mutect2, varscan2
- CPLANE1 | c.*2678G>A | 3'UTR (SNP) | VAF 12/57 reads (21%) | catalogued as rs751692515, COSV57075237; called by muse, mutect2, varscan2
- DCAF13 | c.-29C>G | 5'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as rs762435482, COSV52569558; called by muse, mutect2
- FILIP1L | c.3381+20G>A | Intron (SNP) | VAF 73/77 reads (95%) | catalogued as COSV100497148; called by muse, mutect2, varscan2
- LIN9 | c.244+511G>A | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs1381528792, COSV60246651; called by muse, mutect2, varscan2
- UNKL | c.734+512G>A | Intron (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100061656; called by muse, mutect2, varscan2
